Somatic mutation profile of tumor specimen TCGA-F5-6864-01A (aliquot TCGA-F5-6864-01A-11D-1924-10) from TCGA case TCGA-F5-6864, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 74.1 years (27,058 days).
Specimen TCGA-F5-6864-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db205d98-6acc-4dbf-b5f1-20301437270a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6864-10A (Blood Derived Normal), aliquot TCGA-F5-6864-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05e82611-bcfc-4da0-90f6-cfadb7bd8b80

The open-access MAF lists 138 somatic variants for this specimen: 113 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 22, Frame Shift Del 5, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 2, Intron 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1611C>G p.D537E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61684926, COSV61687202; called by muse, mutect2, varscan2
- SMARCA4 | c.2576C>T p.T859M | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281875226, CM122491, COSV60797919; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as rs587781845, COSV52671445, COSV52701260, COSV52703282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZEB1 | c.1576dup p.V526Gfs*3 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | catalogued as rs766305306; ClinVar: pathogenic; called by mutect2, varscan2
- ADAMTS12 | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs377712954, COSV61260425; called by muse, mutect2, varscan2
- ADCY1 | c.2515A>G p.N839D | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52036139; called by muse, mutect2
- ATP10A | c.4172C>T p.P1391L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs780073022, COSV63518821; called by muse, mutect2, varscan2
- BCL11A | c.1888G>A p.A630T (on ENST00000335712 / NM_001365609.1; = p.A664T on NM_018014.4) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100185319, COSV59632438; called by muse, mutect2, varscan2
- C3AR1 | c.585G>T p.R195S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs1178471418, COSV50819583; called by muse, mutect2, varscan2
- CELSR1 | c.5500C>T p.R1834C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs748872972, COSV53092408; called by muse, mutect2, varscan2
- CEP290 | c.4588A>G p.K1530E | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748206094, COSV58352711; called by muse, mutect2, varscan2
- CTSD | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs200303993, COSV52588586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX24 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as rs764925566, COSV58212780; called by muse, mutect2, varscan2
- DENND3 | c.2787C>G p.F929L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV99370589; called by muse, mutect2
- DEPDC5 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56700323; called by muse, mutect2, varscan2
- DNAH7 | c.10426G>T p.E3476* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100414493; called by muse, mutect2, varscan2
- DNAH9 | c.6517C>T p.R2173W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs774222974, COSV52340595; called by mutect2, varscan2
- DNAJC6 | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as rs762410856, COSV54769895; called by muse, mutect2, varscan2
- DOCK4 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV70322134; called by muse, mutect2, varscan2
- DOP1A | c.3094G>A p.D1032N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV52711848; called by muse, mutect2, varscan2
- DRC7 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs151301678; called by muse, mutect2, varscan2
- DUOX1 | c.4546G>A p.G1516R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747262030, COSV52051094; called by muse, mutect2, varscan2
- EMC8 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.766); catalogued as rs754565994, COSV53666910; called by muse, mutect2, varscan2
- EMILIN1 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.906); catalogued as COSV53155289; called by muse, mutect2, varscan2
- F10 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs566300775, COSV65022117; called by muse, mutect2, varscan2
- FAM135B | c.3689G>A p.R1230Q | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52706937, COSV99426607; called by muse, mutect2, varscan2
- FAT4 | c.14362G>A p.G4788R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138173652, COSV58704889; called by muse, mutect2, varscan2
- FGF5 | c.35G>A p.S12N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.261); catalogued as COSV100427821; called by muse, varscan2
- FUT9 | c.721T>C p.Y241H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100133294; called by muse, mutect2
- GABPA | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61396593; called by muse, mutect2, varscan2
- GALNT14 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs769014379, COSV61106398; called by muse, mutect2, varscan2
- GPR137 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs778003446, COSV57402503; called by muse, mutect2, varscan2
- GRM1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51170045; called by muse, mutect2, varscan2
- H1-7 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV58602317; called by muse, mutect2
- HABP2 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1565104957, COSV63637042; called by muse, mutect2, varscan2
- HCN4 | c.1737G>A p.E579= | Splice Region (SNP) | VAF 10/45 reads (22%) | catalogued as COSV56084455; called by muse, mutect2
- HFM1 | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54029447; called by muse, mutect2
- HNRNPAB | c.606del p.F202Lfs*7 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | catalogued as COSV57423440; called by mutect2, pindel, varscan2
- IL31RA | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs980333781, COSV51682465; called by muse, mutect2, varscan2
- IP6K3 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.035); catalogued as rs142228010; called by muse, mutect2
- KIF22 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764389481, COSV50715610; called by muse, mutect2, varscan2
- KLF5 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867921927, COSV66614545, COSV66614659; called by muse, mutect2, varscan2
- KRTAP9-2 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV100893151; called by muse, mutect2
- LSM14A | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV70885220; called by muse, mutect2, varscan2
- MACF1 | c.3864C>G p.I1288M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100483448; called by muse, mutect2, varscan2
- MAMSTR | c.815C>G p.P272R (on ENST00000318083 / NM_001130915.2; = p.P169R on NM_182574.2) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV58881877; called by muse, mutect2, varscan2
- MAP3K11 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV58420345; called by muse, mutect2
- MAP3K21 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773185929, COSV64044097; called by muse, mutect2, varscan2
- MAP3K9 | c.3059C>A p.P1020Q (on ENST00000554752 / NM_001284230.1; = p.P1034Q on NM_033141.4) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV67121700; called by muse, mutect2, varscan2
- MAST4 | c.2406G>T p.W802C (on ENST00000403625 / NM_001164664.2; = p.W613C on NM_015183.3) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55129169; called by muse, mutect2, varscan2
- MICAL2 | c.819A>T p.K273N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV56320326; called by muse, mutect2, varscan2
- MKRN3 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV58810292; called by muse, mutect2, varscan2
- MRPL15 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV52637728; called by muse, mutect2, varscan2
- MUC5B | c.10397C>T p.T3466M | Missense Mutation (SNP) | VAF 106/356 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs762917439, COSV71590951; called by muse, mutect2
- MYH6 | c.3574G>A p.A1192T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs574066490, COSV100676403; called by muse, mutect2, varscan2
- NID2 | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs145229633; called by muse, mutect2, varscan2
- NRXN2 | c.3238G>A p.A1080T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1198639219, COSV55455607; called by muse, mutect2, varscan2
- OR8H2 | c.308T>G p.F103C | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs775438114, COSV57945320; called by muse, varscan2
- OR8H3 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs557395205, COSV57909504; called by muse, varscan2
- OXSM | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs769097304, COSV55001849; called by muse, mutect2, varscan2
- PCDH11X | c.1505A>G p.N502S | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV53474751; called by muse, varscan2
- PCLO | c.4768del p.E1590Rfs*14 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as COSV61641500; called by mutect2, pindel, varscan2
- PDCD1LG2 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV101173084; called by muse, mutect2
- PEG3 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as rs751288968, COSV55634973, COSV99688124; called by muse, mutect2, varscan2
- PGS1 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.349); catalogued as rs775469312, COSV53146050; called by muse, mutect2, varscan2
- PITRM1 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442467139, COSV56533161; called by muse, mutect2, varscan2
- PKD1 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs752848157; called by muse, mutect2
- PLPPR4 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as rs751443691, COSV100926794, COSV64564662; called by muse, mutect2, varscan2
- PPM1K | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.31); catalogued as rs150935940, COSV55796527; called by muse, mutect2, varscan2
- PRKAR1A | c.797C>A p.T266K | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.519); catalogued as COSV62235817, COSV62235861; called by muse, mutect2, varscan2
- PRXL2A | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV64690806; called by muse, mutect2, varscan2
- PTCHD1 | c.2071C>G p.R691G | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV101037965, COSV65061142, COSV65062604; called by muse, mutect2, varscan2
- RFPL3 | c.556G>A p.V186M (on ENST00000249007 / NM_001098535.1; = p.V157M on NM_006604.2) | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); catalogued as rs757286389, COSV50749796; called by muse, mutect2, varscan2
- RHOT2 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs143577577, COSV53473506; called by muse, mutect2
- ROS1 | c.1598A>C p.D533A | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV100876764; called by muse, mutect2, varscan2
- RPS26 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV62887472; called by muse, mutect2, varscan2
- RUFY2 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as COSV61190801, COSV61191429; called by muse, mutect2, varscan2
- RYR1 | c.11608G>A p.G3870R | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs1306190316, COSV62100309; called by muse, mutect2, varscan2
- SEMA3E | c.2293C>A p.H765N | Missense Mutation (SNP) | VAF 172/333 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV57094448; called by muse, mutect2, varscan2
- SHD | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73378736; called by muse, varscan2
- SLC4A3 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435905911, COSV56094705; called by muse, mutect2, varscan2
- SLC5A2 | c.1452C>T p.G484= | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as rs1481942949, COSV57892374; called by muse, mutect2, varscan2
- SMAD3 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs886039050, COSV59285115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX29 | c.1850A>T p.E617V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV60061970; called by muse, mutect2, varscan2
- SORCS3 | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63795716; called by muse, mutect2, varscan2
- SRRM3 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs190294181, COSV100418635; called by muse, mutect2
- ST8SIA2 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | PolyPhen possibly damaging (0.472); catalogued as rs772349659, COSV51570113; called by muse, mutect2, varscan2
- SYNE2 | c.4138T>C p.C1380R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59954388; called by muse, mutect2
- SYNM | c.2950G>A p.V984M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs369298488; called by muse, mutect2, varscan2
- TBCA | c.30G>C p.K10N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV60539117; called by muse, mutect2, varscan2
- TMCO4 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs570405680, COSV53869004; called by muse, mutect2, varscan2
- TMEM106A | c.143G>C p.C48S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.093); catalogued as COSV57831291, COSV57833268; called by muse, mutect2, varscan2
- TPO | c.2406C>A p.D802E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as COSV61094587, COSV61102965; called by muse, mutect2, varscan2
- TTN | c.67277G>T p.G22426V (on ENST00000591111; = p.G15002V on NM_003319.4) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | PolyPhen probably damaging (0.925); catalogued as COSV100589376, COSV60127735; called by muse, mutect2, varscan2
- TTN | c.42815T>A p.L14272H (on ENST00000591111; = p.L6848H on NM_003319.4) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | PolyPhen possibly damaging (0.79); catalogued as COSV60127763; called by muse, mutect2, varscan2
- TTN | c.24503T>A p.I8168N (on ENST00000591111; = p.I7241N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | PolyPhen possibly damaging (0.486); catalogued as COSV60127786; called by muse, mutect2, varscan2
- TXNRD2 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV57633645; called by muse, mutect2
- VCAN | c.6208A>G p.K2070E | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1292246718, COSV54107581; called by muse, mutect2, varscan2
- VPS33A | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.407); catalogued as rs774697260, COSV57357389, COSV57359377; called by muse, mutect2, varscan2
- WDFY3 | c.4811T>C p.V1604A | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV55703811; called by muse, mutect2, varscan2
- WDR35 | c.1412C>A p.S471Y (on ENST00000345530 / NM_001006657.2; = p.S460Y on NM_020779.4) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs1158391761, COSV55603926; called by muse, mutect2, varscan2
- ZBED9 | c.2119C>A p.H707N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV71729485; called by muse, mutect2, varscan2
- ZEB2 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57961261; called by muse, mutect2, varscan2
- ZFP37 | c.1694G>T p.R565I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs764115618, COSV65286894; called by muse, mutect2, varscan2
- ZNF260 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs749233923, COSV72951232; called by muse, mutect2, varscan2
- ZNF569 | c.1973G>A p.G658D | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57596248; called by muse, mutect2, varscan2
- ZNF713 | c.1226G>T p.R409L (on ENST00000633730 / NM_001366796.2; = p.R422L on NM_182633.3) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV70056968; called by muse, mutect2, varscan2
- DEFB106B | c.66del p.F22Lfs*30 | Frame Shift Del (DEL) | VAF 58/160 reads (36%) | called by mutect2, varscan2
- KCNJ6 | c.321del p.F107Lfs*3 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- LCMT2 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2
- MAGEB6 | c.650dup p.L217Ffs*35 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- STON2 | c.2460del p.F820Lfs*13 (on ENST00000649389 / NM_001366849.2; = p.F763Lfs*13 on NM_001256430.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- ACTC1 | c.75C>T p.G25= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs144819872, COSV51759615; called by muse, mutect2, varscan2
- ANAPC11 | c.57C>T p.N19= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs776080835, COSV58668663; called by muse, mutect2, varscan2
- ATP10A | c.816G>A p.T272= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs375266969, COSV63518825; called by mutect2, varscan2
- DNAI1 | c.2049G>A p.A683= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs555612830, COSV54278352; called by muse, mutect2, varscan2
- GGA3 | c.30G>A p.E10= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs1305919787, COSV55453636, COSV55453806; called by muse, mutect2, varscan2
- GPR62 | c.96C>T p.N32= | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as COSV59054702; called by muse, mutect2, varscan2
- HAPLN3 | c.780C>T p.F260= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs753937906, COSV61362284; called by muse, mutect2, varscan2
- HJURP | c.963G>A p.K321= | Silent (SNP) | VAF 50/155 reads (32%) | catalogued as COSV64978733; called by muse, mutect2, varscan2
- LAPTM4B | c.939T>G p.P313= (on ENST00000445593; = p.P222= on NM_018407.6) | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs111541249, COSV71454276; called by muse, mutect2
- MON2 | c.774G>A p.P258= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as rs768154548, COSV54808956; called by muse, mutect2, varscan2
- MTUS2 | c.2037C>A p.P679= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV70917347; called by muse, mutect2
- MYO16 | c.5010C>T p.S1670= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV62751875; called by muse, mutect2, varscan2
- OR4D5 | c.756G>A p.V252= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as COSV58307559; called by muse, mutect2
- PLA1A | c.999T>C p.S333= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV99845762; called by mutect2, varscan2
- SBK2 | c.33G>A p.A11= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs950736459, COSV60013178; called by muse, mutect2
- SZT2 | c.6501G>A p.G2167= (on ENST00000634258 / NM_001365999.1; = p.G2110= on NM_015284.4) | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs1357821442, COSV65170814; called by muse, mutect2, varscan2
- THUMPD3 | c.138T>A p.T46= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV61506191; called by muse, mutect2, varscan2
- TP73 | c.1842C>T p.F614= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs1275983986, COSV60702918; called by muse, mutect2
- TSC2 | c.1554C>A p.G518= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1274545629, COSV54767970; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSPAN32 | c.612C>T p.I204= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs977477028, COSV51718934; called by muse, mutect2, varscan2
- ZNF560 | c.384C>T p.D128= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV56868695; called by muse, mutect2, varscan2
- ZNF629 | c.528G>A p.R176= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV52699061; called by muse, mutect2, varscan2
- GABRB3 | chr15:26773673 G>C | 5'Flank (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100159023; called by muse, mutect2
- RBM44 | c.-98-1939G>C | Intron (SNP) | VAF 30/91 reads (33%) | catalogued as COSV100390004, COSV57630330; called by muse, mutect2, varscan2
- RIBC2 | c.*2G>A | 3'UTR (SNP) | VAF 90/286 reads (31%) | catalogued as COSV100734115; called by muse, varscan2
